Somatic mutation profile of tumor specimen 0DWQ45 from CCDI case PBCPFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 20.2 years (7,383 days).
Specimen 0DWQ45: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa7b0536-64ba-49bf-b193-f9ff62b496b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWQ3V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8991208e-330a-4d75-b88c-ea40971ca5da

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 307/708 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SETBP1 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 347/749 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607040, CM103049, CM148164, COSV56311834, COSV56315308; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- BDH1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 195/402 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs757702931; called by muse, varscan2
- ENPP5 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 373/855 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs201147736, COSV57908513; called by muse, mutect2, varscan2
- HDAC7 | c.681G>A p.A227= (on ENST00000427332; = p.A266= on NM_015401.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/173 reads (13%) | catalogued as rs376627238; called by muse, mutect2, varscan2
- KIF4A | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 365/913 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV104428446; called by muse, mutect2, varscan2
- LAMA3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 372/844 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs753622480; called by muse, mutect2, varscan2
- NWD1 | c.3508G>A p.V1170I | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs751532845; called by muse, mutect2, varscan2
- OR8I2 | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 410/950 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs752960753; called by muse, mutect2, varscan2
- PRKAR1A | c.953T>G p.L318W | Missense Mutation (SNP) | VAF 249/605 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62236674; called by muse, mutect2, varscan2
- R3HDML | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 304/1064 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as rs577662569; called by muse, mutect2, varscan2
- SLIT1 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 379/865 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs776229210; called by muse, mutect2, varscan2
- TAF1 | c.3800C>T p.A1267V (on ENST00000373790 / NM_138923.4; = p.A1288V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/808 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1475300074, COSV52115620, COSV52119736; called by muse, mutect2, varscan2
- ZNF616 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 305/740 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs536049886, COSV57510590; called by muse, mutect2, varscan2
- ZNF98 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 223/550 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1568289712, COSV63335140, COSV63335366; called by muse, mutect2, varscan2
- AC244197.3 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 358/748 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- C10orf71 | c.2713T>A p.F905I | Missense Mutation (SNP) | VAF 169/317 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC150 | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 388/893 reads (43%) | called by muse, mutect2, varscan2
- CCNA2 | c.324dup p.E109Rfs*8 | Frame Shift Ins (INS) | VAF 350/802 reads (44%) | called by mutect2, varscan2
- CD40 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 70/1422 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2
- KDM6A | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 313/646 reads (48%) | called by muse, mutect2, varscan2
- RPA4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 475/1047 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SHANK3 | c.2595G>T p.E865D | Missense Mutation (SNP) | VAF 204/434 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A11 | c.1189del p.W397Gfs*11 | Frame Shift Del (DEL) | VAF 408/904 reads (45%) | called by mutect2, varscan2
- WDR77 | c.35del p.P12Rfs*38 | Frame Shift Del (DEL) | VAF 120/310 reads (39%) | called by mutect2, varscan2
- ZBTB3 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 23/545 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ZIC5 | c.638A>C p.H213P | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.429); called by muse, mutect2
- ACP7 | c.291G>A p.T97= | Silent (SNP) | VAF 269/593 reads (45%) | catalogued as COSV58700405; called by muse, varscan2
- CYP1A1 | c.426G>A p.L142= | Silent (SNP) | VAF 98/517 reads (19%) | called by muse, mutect2, varscan2
- PCDH8 | c.1353C>G p.T451= | Silent (SNP) | VAF 120/281 reads (43%) | called by muse, mutect2, varscan2
- SLC35G5 | c.333C>T p.N111= | Silent (SNP) | VAF 348/858 reads (41%) | catalogued as rs769673349; called by muse, varscan2
- SUPT20HL2 | c.2358C>T p.G786= | Silent (SNP) | VAF 275/666 reads (41%) | catalogued as rs772724290; called by muse, mutect2, varscan2
- TIAM2 | c.1906C>T p.L636= | Silent (SNP) | VAF 65/1017 reads (6%) | called by muse, mutect2
- USP17L2 | c.852C>T p.S284= | Silent (SNP) | VAF 220/938 reads (23%) | catalogued as rs568636393; called by muse, mutect2, varscan2
- CHRNB4 | chr15:78641215 G>A | 5'Flank (SNP) | VAF 41/90 reads (46%) | catalogued as rs1055239844; called by muse, mutect2, varscan2
- DLG2 | c.*58_*59dup | 3'UTR (INS) | VAF 60/128 reads (47%) | called by mutect2, varscan2
- NGF | c.*93C>T | 3'UTR (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- PGM3 | c.-2-206G>T | Intron (SNP) | VAF 317/752 reads (42%) | called by muse, mutect2, varscan2
- TMEM42 | c.192+83_192+91del | Intron (DEL) | VAF 15/55 reads (27%) | called by mutect2, varscan2
